Somatic mutation profile of tumor specimen TCGA-G3-AAV5-01A (aliquot TCGA-G3-AAV5-01A-11D-A36X-10) from TCGA case TCGA-G3-AAV5, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 67.5 years (24,655 days).
Specimen TCGA-G3-AAV5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 348eff75-06ba-4983-b7cc-cb5597238633.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-AAV5-10A (Blood Derived Normal), aliquot TCGA-G3-AAV5-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ed951e9-89c4-4d0d-b750-80fbfb6450d0

The open-access MAF lists 80 somatic variants for this specimen: 61 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 48, Silent 19, Nonsense Mutation 8, Frame Shift Ins 2, In Frame Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 73/165 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 28/101 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11671C>T p.L3891F | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101446907; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2632G>A p.V878I | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1342175574; called by muse, mutect2, varscan2
- ADNP | c.1202C>G p.S401C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100823698; called by muse, mutect2, varscan2
- ANK3 | c.9925C>A p.P3309T | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV99779407; called by muse, mutect2, varscan2
- ARHGAP9 | c.1663G>T p.V555L (on ENST00000393797 / NM_001319850.2; = p.V536L on NM_032496.4) | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99953983; called by muse, mutect2, varscan2
- ARHGEF11 | c.2939A>T p.K980M | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100168476; called by muse, mutect2, varscan2
- ARHGEF3 | c.1492G>T p.D498Y | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.735); catalogued as COSV56332245, COSV99575186; called by muse, mutect2, varscan2
- ARHGEF7 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.003); catalogued as COSV100404916; called by muse, mutect2, varscan2
- ATP5F1B | c.521T>C p.M174T | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV100008059; called by muse, mutect2, varscan2
- BAIAP3 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as COSV100181328; called by muse, mutect2, varscan2
- BAX | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV53170903, COSV99509048; called by muse, mutect2, varscan2
- BCL6 | c.70C>A p.R24S | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99215556; called by muse, mutect2, varscan2
- CDAN1 | c.2731C>G p.P911A | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1231592816, COSV100661255; called by muse, mutect2, varscan2
- CILP | c.2752G>T p.E918* | Nonsense Mutation (SNP) | VAF 39/110 reads (35%) | catalogued as COSV99973154; called by muse, mutect2, varscan2
- COL27A1 | c.3146C>T p.P1049L | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.376); catalogued as COSV100620901; called by muse, mutect2, varscan2
- DYSF | c.828G>C p.E276D | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99245987; called by muse, mutect2, varscan2
- EPPK1 | c.6691G>T p.V2231L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV101599800; called by muse, mutect2, varscan2
- FAM209B | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.143); catalogued as COSV100990946; called by muse, mutect2
- HECTD4 | c.11113C>T p.Q3705* | Nonsense Mutation (SNP) | VAF 46/122 reads (38%) | catalogued as COSV101107221; called by muse, mutect2, varscan2
- IGDCC4 | c.1769C>A p.S590* | Nonsense Mutation (SNP) | VAF 33/96 reads (34%) | catalogued as rs757318390, COSV100732822; called by muse, mutect2, varscan2
- IRS1 | c.2846G>A p.G949D | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV100524340; called by muse, mutect2, varscan2
- KRT35 | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as COSV55844307; called by muse, mutect2, varscan2
- LASP1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100530347; called by muse, mutect2, varscan2
- MALSU1 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs375849242; called by muse, mutect2, varscan2
- METTL17 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.904); catalogued as COSV100228162; called by muse, mutect2, varscan2
- MGA | c.1292A>G p.N431S | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs764153763, COSV99579442; called by muse, mutect2, varscan2
- MIB2 | c.298C>G p.P100A | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as COSV100598846; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1946C>T p.T649I | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs775227679, COSV100825064; called by muse, mutect2, varscan2
- MUC17 | c.1900A>G p.M634V | Missense Mutation (SNP) | VAF 47/96 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100072694; called by muse, mutect2, varscan2
- NOVA1 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 37/128 reads (29%) | catalogued as COSV99947182; called by muse, mutect2, varscan2
- NPHS2 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100858153; called by muse, mutect2, varscan2
- NRXN3 | c.437G>T p.G146V (on ENST00000557594 / NM_001272020.2; = p.G778V on NM_004796.6) | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55333107, COSV99817861; called by muse, mutect2, varscan2
- OR10A3 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.549); catalogued as COSV100660257, COSV62459951; called by muse, varscan2
- PCMT1 | c.503A>G p.D168G | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100953416; called by muse, mutect2
- PDIA2 | c.808A>T p.I270F | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99249626; called by muse, mutect2, varscan2
- PODNL1 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.107); catalogued as rs763293497, COSV99582828; called by muse, mutect2, varscan2
- PTPRA | c.1566C>G p.Y522* | Nonsense Mutation (SNP) | VAF 51/152 reads (34%) | catalogued as COSV99399584; called by muse, mutect2, varscan2
- QPCTL | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.996); catalogued as COSV99171253; called by muse, mutect2, varscan2
- RASAL2 | c.2692G>A p.G898R | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.728); catalogued as rs368617203; called by muse, mutect2, varscan2
- RBM6 | c.1645A>G p.I549V | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1395704060, COSV99805096; called by muse, mutect2, varscan2
- SCP2 | c.675T>G p.C225W | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101026987, COSV65260474; called by muse, mutect2, varscan2
- SLC12A4 | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100311652; called by muse, mutect2, varscan2
- SUFU | c.1401G>T p.K467N | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as COSV100883357, COSV64017787; called by muse, mutect2, varscan2
- SYT14 | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 148/726 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs267598355, COSV99654981; called by muse, mutect2, varscan2
- TAF1L | c.4414G>T p.V1472L | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs1426409183, COSV99644471; called by muse, mutect2, varscan2
- TAPT1 | c.427A>G p.T143A | Missense Mutation (SNP) | VAF 159/416 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV101301478; called by muse, mutect2, varscan2
- TBX3 | c.493T>A p.F165I | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99983668; called by muse, mutect2, varscan2
- TCTN1 | c.1205A>T p.Q402L (on ENST00000551590 / NM_001173975.3; = p.Q388L on NM_024549.6) | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV100885966; called by muse, mutect2, varscan2
- TG | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 64/285 reads (22%) | catalogued as rs765980140, COSV99600224; called by muse, mutect2, varscan2
- TRIB1 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.257); catalogued as COSV100322446; called by muse, mutect2, varscan2
- TRPV4 | c.772G>T p.V258L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV99924590; called by muse, mutect2, varscan2
- TSKS | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV55876573; called by muse, mutect2, varscan2
- USP22 | c.650G>A p.S217N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99820203; called by muse, mutect2, varscan2
- ZNF862 | c.195G>A p.W65* | Nonsense Mutation (SNP) | VAF 188/332 reads (57%) | catalogued as COSV99783420; called by muse, mutect2, varscan2
- AFM | c.1120_1121insAG p.V374Efs*9 | Frame Shift Ins (INS) | VAF 30/107 reads (28%) | called by mutect2, pindel, varscan2
- ALB | c.482dup p.Y162Ifs*4 | Frame Shift Ins (INS) | VAF 31/99 reads (31%) | called by mutect2, pindel, varscan2
- ALB | c.1428+2_1428+3del p.X476_splice | Splice Site (DEL) | VAF 55/175 reads (31%) | called by pindel, varscan2
- C16orf86 | c.462_473del p.K155_K158del | In Frame Del (DEL) | VAF 33/114 reads (29%) | called by mutect2, pindel, varscan2
- RAB11FIP3 | c.1929_1937del p.G644_S646del | In Frame Del (DEL) | VAF 21/62 reads (34%) | called by mutect2, pindel, varscan2
- ADGRA3 | c.2841G>A p.E947= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as COSV99293164; called by muse, mutect2, varscan2
- ADGRE5 | c.2268C>G p.G756= (on ENST00000242786 / NM_078481.4; = p.G663= on NM_001784.5) | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV99660243; called by muse, mutect2, varscan2
- ALYREF | c.360G>A p.L120= | Silent (SNP) | VAF 59/117 reads (50%) | catalogued as rs759837859, COSV100485820; called by muse, mutect2, varscan2
- BTAF1 | c.723G>A p.E241= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV99795197; called by muse, mutect2, varscan2
- EIF1AD | c.255G>A p.S85= | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as rs778490397, COSV100381367; called by muse, mutect2, varscan2
- EN2 | c.228G>A p.R76= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as rs1008034976, COSV99818593; called by muse, mutect2, varscan2
- EPPK1 | c.6690G>C p.L2230= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV101599801, COSV73260826; called by muse, mutect2, varscan2
- FAM111B | c.453T>C p.P151= | Silent (SNP) | VAF 49/122 reads (40%) | catalogued as COSV100639263; called by muse, mutect2, varscan2
- GPC2 | c.1404G>A p.R468= | Silent (SNP) | VAF 60/207 reads (29%) | catalogued as COSV99444544; called by muse, mutect2, varscan2
- MED13 | c.6210A>T p.S2070= | Silent (SNP) | VAF 118/186 reads (63%) | catalogued as COSV101180950; called by muse, varscan2
- MUC4 | c.15757C>T p.L5253= (on ENST00000463781 / NM_018406.7; = p.L1017= on NM_004532.6) | Silent (SNP) | VAF 53/120 reads (44%) | catalogued as rs542498469, COSV100204293; called by muse, mutect2, varscan2
- OR5W2 | c.426T>C p.Y142= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV100747588; called by muse, mutect2, varscan2
- PARP10 | c.2055C>T p.L685= | Silent (SNP) | VAF 21/163 reads (13%) | catalogued as rs1554748296, COSV100477919; called by muse, mutect2, varscan2
- RASSF3 | c.462C>T p.Y154= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as rs756092933, COSV51685430; called by muse, mutect2, varscan2
- RHEX | c.294C>T p.S98= | Silent (SNP) | VAF 46/228 reads (20%) | catalogued as COSV100520074; called by muse, mutect2, varscan2
- SMG1 | c.5223C>T p.F1741= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as COSV101245639; called by muse, mutect2, varscan2
- TAF11 | c.546A>G p.L182= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV99511740; called by muse, mutect2, varscan2
- TAF1L | c.4284C>A p.V1428= | Silent (SNP) | VAF 71/231 reads (31%) | catalogued as COSV99644473; called by muse, mutect2, varscan2
- UPF3A | c.1062A>G p.Q354= | Silent (SNP) | VAF 101/240 reads (42%) | catalogued as COSV100677573; called by muse, mutect2, varscan2
